Somatic mutation profile of tumor specimen C3L-01632-02 (aliquot CPT0086750009) from CPTAC case C3L-01632, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,145 days).
Specimen C3L-01632-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73d31a03-f15b-4763-82b1-ab6dad315220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01632-31 (Blood Derived Normal), aliquot CPT0087410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a711885-5407-4d81-a021-4137088636fb

The open-access MAF lists 229 somatic variants for this specimen: 155 protein-altering or splice-affecting, 48 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 48, Nonsense Mutation 15, Intron 10, RNA 8, Frame Shift Del 7, Splice Site 6, 3'UTR 4, Splice Region 3, 3'Flank 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 55/266 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM4 | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101257063; called by muse, mutect2, varscan2
- AGBL1 | c.2374+1G>T p.X792_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV66863852; called by muse, mutect2
- ANKRD26 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV101066613, COSV101066655; called by muse, mutect2
- BHMT2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as COSV54875188; called by muse, mutect2, varscan2
- BTBD2 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs149233510; called by muse, mutect2
- C9 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs372918983; called by muse, mutect2, varscan2
- CHRM2 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV57776577; called by muse, mutect2, varscan2
- COL9A1 | c.144G>T p.R48S | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV61830226; called by muse, mutect2
- CRIM1 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs764178371; called by muse, mutect2, varscan2
- CSMD3 | c.3809G>T p.S1270I (on ENST00000297405 / NM_001363185.1; = p.S1166I on NM_052900.3) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52114161, COSV52156610; called by muse, varscan2
- EFCAB7 | c.1154A>C p.D385A | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1028690681; called by muse, mutect2, varscan2
- ENAM | c.2361G>T p.W787C | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748480572, COSV68536135; called by muse, mutect2, varscan2
- FCRL5 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.036); catalogued as rs778238010; called by muse, mutect2
- GAL3ST2 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as COSV51949475; called by muse, mutect2, varscan2
- GRM7 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs750418695; called by muse, mutect2, varscan2
- HS3ST5 | c.606del p.K203Rfs*13 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | catalogued as COSV57136437; called by mutect2, pindel
- KEAP1 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50261093; called by muse, mutect2, varscan2
- KIAA1217 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs200657746, COSV56812686; called by muse, mutect2, varscan2
- LCP2 | c.426C>G p.D142E | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV50450599; called by muse, mutect2, varscan2
- LGI1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 128/505 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65057685; called by muse, mutect2, varscan2
- MGAM | c.2523C>G p.I841M | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV101527409; called by muse, mutect2, varscan2
- MTUS2 | c.3568C>A p.L1190M (on ENST00000612955 / NM_001366650.1; = p.L169M on NM_015233.6) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60158367; called by muse, mutect2, varscan2
- NDUFA6 | c.310A>T p.M104L | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1164226793; called by muse, mutect2, varscan2
- NLRP3 | c.1505G>T p.R502M | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60224327; called by muse, mutect2, varscan2
- NTRK3 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV62295252, COSV62297183; called by muse, mutect2, varscan2
- OR14C36 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV58601206, COSV58602950; called by muse, mutect2, varscan2
- OR4X1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 21/181 reads (12%) | catalogued as rs151032486; called by muse, mutect2, varscan2
- OR5J2 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV100399231, COSV56622158; called by muse, mutect2, varscan2
- OR5L1 | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV61734790; called by muse, mutect2, varscan2
- PCDH15 | c.2310C>A p.S770R | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs777745189; called by muse, mutect2, varscan2
- PCDH17 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100931409, COSV64974304; called by muse, mutect2, varscan2
- PKP1 | c.1255C>A p.L419I | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.069); catalogued as COSV55820059; called by muse, mutect2
- PRAG1 | c.2716G>T p.G906W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs200130163; called by muse, mutect2, varscan2
- RAD51C | c.966-1G>T p.X322_splice | Splice Site (SNP) | VAF 34/268 reads (13%) | catalogued as rs876658272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM38 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61135193; called by muse, mutect2, varscan2
- RREB1 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 18/147 reads (12%) | catalogued as COSV58565678; called by muse, mutect2
- SLITRK2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 38/226 reads (17%) | catalogued as COSV59425285; called by muse, mutect2, varscan2
- SMARCA4 | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60798133, COSV60813326; called by muse, mutect2
- SMYD3 | c.344G>C p.G115A (on ENST00000490107 / NM_001375962.1; = p.G56A on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV66456690; called by muse, mutect2, varscan2
- SPTA1 | c.4685G>T p.G1562V | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763995335; called by muse, mutect2, varscan2
- STAMBPL1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as rs1342837752; called by muse, mutect2, varscan2
- TCHHL1 | c.1455C>A p.N485K | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV64285426; called by muse, mutect2, varscan2
- TMPRSS13 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101471433; called by muse, mutect2, varscan2
- TUBA3C | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV67138735; called by muse, mutect2, varscan2
- USP36 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs756686721; called by muse, mutect2, varscan2
- VCAN | c.5811C>G p.D1937E | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV54099434; called by muse, mutect2
- VRK1 | c.-4G>A | Splice Region (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99388571; called by muse, mutect2
- ZNF692 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60659928; called by muse, mutect2, varscan2
- ZNF804B | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 44/223 reads (20%) | catalogued as rs950169909, COSV60827475; called by muse, mutect2, varscan2
- ABCC4 | c.2176-1G>T p.X726_splice | Splice Site (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- ACTN4 | c.1917G>T p.E639D | Missense Mutation (SNP) | VAF 70/491 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS5 | c.1544C>A p.A515D | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- ADSS2 | c.231T>A p.Y77* | Nonsense Mutation (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- AFF2 | c.3617dup p.N1206Kfs*24 | Frame Shift Ins (INS) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- ALAS1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2
- ANK1 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2
- ANKRD62 | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- AOC1 | c.2057C>A p.A686D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ARHGAP21 | c.5722A>T p.R1908W | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF15 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2
- ARMC3 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ASB14 | c.1235T>A p.V412D | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASPM | c.5234G>T p.R1745L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCR | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAMTA1 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC73 | c.958del p.E320Sfs*7 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- CDH10 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CEP164 | c.4142G>T p.R1381M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CNTN5 | c.584del p.G195Efs*13 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.3953A>G p.N1318S | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNTNAP2 | c.3643G>T p.G1215W | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL12A1 | c.4147G>T p.G1383C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- CSMD3 | c.3807T>A p.Y1269* (on ENST00000297405 / NM_001363185.1; = p.Y1165* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | called by muse, varscan2
- DGLUCY | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DIO2 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DISC1 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- DLAT | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DLX3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH3 | c.12220G>C p.A4074P | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH5 | c.13434C>A p.H4478Q | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DOCK3 | c.6079C>T p.R2027* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- DRP2 | c.2298G>T p.E766D | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENAM | c.2360G>T p.W787L | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, varscan2
- FAM102B | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- FAM171B | c.2462C>A p.P821Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, varscan2
- FAM9C | c.438+1G>T p.X146_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- FANCD2 | c.3945C>G p.F1315L | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.077); called by muse, mutect2
- FBN2 | c.5060C>A p.T1687N | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, varscan2
- FSTL5 | c.1086C>A p.C362* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- GABRG1 | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- GAS2L1 | c.300del p.D101Tfs*100 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel*, varscan2
- GDF2 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HBG1 | c.316-8C>A | Splice Region (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- HDAC6 | c.737+1G>T p.X246_splice | Splice Site (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- HOXA10 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- IL10RA | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- KANSL1 | c.2553G>T p.R851S (on ENST00000574590 / NM_001193465.2; = p.R852S on NM_015443.4) | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KASH5 | c.940C>A p.R314S | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNH8 | c.2782T>G p.W928G | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.13); called by muse, mutect2
- KIAA1841 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- LAMA4 | c.5290G>T p.D1764Y (on ENST00000230538 / NM_001105206.3; = p.D1757Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMC2 | c.1393C>A p.H465N | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LILRB3 | c.822dup p.G275Wfs*37 | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- LRRC66 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- LTBP1 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MORC4 | c.1341A>T p.L447F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MSLN | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- MTPAP | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MYO16 | c.3838G>T p.V1280L | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NEK10 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRDC | c.1850A>T p.E617V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR2L2 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OR51F2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- OR5L2 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- OR7G3 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OR7G3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- P2RX1 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PDZRN3 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKFB3 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | PolyPhen probably damaging (0.956); called by muse, mutect2
- PHF6 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHH2 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPEF1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PTPN13 | c.2591A>G p.Q864R | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- RRAGB | c.199A>T p.R67* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- RYR2 | c.4663T>C p.F1555L | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.193); called by muse, varscan2
- RYR3 | c.5026G>C p.G1676R | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SCML2 | c.1411A>T p.R471W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- SERPINA11 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNX9 | c.1649-1G>T p.X550_splice | Splice Site (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- SPAG8 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPATS1 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPECC1 | c.2596C>A p.Q866K | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPTA1 | c.6330G>T p.K2110N | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPTLC1 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TATDN3 | c.509_511delinsTT p.H170Lfs*9 | Frame Shift Del (DEL) | VAF 56/233 reads (24%) | called by pindel, varscan2*
- TCN1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TECPR1 | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TFPI | c.535+2dup | Splice Region (INS) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- TMEM135 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP63 | c.1017del p.F340Lfs*48 | Frame Shift Del (DEL) | VAF 56/331 reads (17%) | called by mutect2, pindel, varscan2
- TRAJ4 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- TRIM49B | c.501C>A p.C167* | Nonsense Mutation (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.1640del p.G547Afs*25 | Frame Shift Del (DEL) | VAF 14/160 reads (9%) | called by mutect2, pindel
- UGT2B11 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13B | c.152_152+2del | In Frame Del (DEL) | VAF 12/90 reads (13%) | called by pindel, varscan2
- UNC13C | c.6067G>T p.A2023S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2
- USH2A | c.14715C>A p.Y4905* | Nonsense Mutation (SNP) | VAF 63/463 reads (14%) | called by muse, mutect2, varscan2
- USP38 | c.1803G>T p.L601F | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- VSTM2L | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WNK3 | c.2597C>A p.S866Y | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF184 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF354C | c.1222G>T p.G408* | Nonsense Mutation (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- ZNF493 | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF792 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ABCA3 | c.1905C>T p.G635= | Silent (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- ACBD3 | c.621G>A p.L207= | Silent (SNP) | VAF 27/262 reads (10%) | called by muse, varscan2
- ADCY8 | c.384C>A p.G128= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV53931826; called by muse, mutect2, varscan2
- AGAP2 | c.1239C>G p.G413= (on ENST00000547588 / NM_001122772.2; = p.G77= on NM_014770.4) | Silent (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- BEND4 | c.1050C>A p.I350= | Silent (SNP) | VAF 11/261 reads (4%) | called by muse, mutect2
- CACNA1G | c.7065G>T p.S2355= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV61721160; called by muse, mutect2, varscan2
- CCT8L2 | c.40C>A p.R14= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs553618420, COSV63461614; called by muse, mutect2, varscan2
- CHIC1 | c.246G>C p.R82= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.333C>A p.T111= | Silent (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2, varscan2
- CRISP3 | c.312C>A p.A104= (on ENST00000371159 / NM_001368123.1; = p.A86= on NM_006061.4) | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV99539299; called by muse, varscan2
- DACT2 | c.1521G>T p.V507= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as COSV64694530; called by muse, mutect2
- DUSP13 | c.396C>A p.G132= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100403971; called by muse, mutect2, varscan2
- ESRRB | c.591G>T p.L197= | Silent (SNP) | VAF 45/436 reads (10%) | catalogued as rs373006116; called by muse, mutect2, varscan2
- F8A1 | c.1095C>T p.S365= | Silent (SNP) | VAF 30/586 reads (5%) | called by muse, mutect2
- FAT3 | c.9453C>A p.T3151= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, varscan2
- FBN2 | c.5049C>A p.L1683= | Silent (SNP) | VAF 59/313 reads (19%) | called by muse, varscan2
- FN3K | c.681C>T p.D227= | Silent (SNP) | VAF 57/303 reads (19%) | catalogued as rs1020794615; called by muse, mutect2, varscan2
- FSTL5 | c.297T>A p.P99= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- GRM4 | c.360G>A p.L120= | Silent (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- INSYN2B | c.1245A>C p.R415= | Silent (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- KLRC2 | c.441G>T p.S147= | Silent (SNP) | VAF 53/235 reads (23%) | catalogued as COSV101122746; called by muse, mutect2, varscan2
- LCMT2 | c.2060A>G p.*687= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1218607843; called by muse, mutect2, varscan2
- LRP2 | c.195G>T p.V65= | Silent (SNP) | VAF 72/426 reads (17%) | called by mutect2, varscan2
- MCF2 | c.990C>A p.L330= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- METTL1 | c.16C>A p.R6= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- MICAL3 | c.2694G>T p.L898= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- MYH8 | c.5163C>A p.T1721= | Silent (SNP) | VAF 74/374 reads (20%) | called by muse, mutect2, varscan2
- NBAS | c.159G>T p.T53= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as COSV55718442, COSV55722162; called by muse, mutect2, varscan2
- NLRP3 | c.1578C>T p.F526= | Silent (SNP) | VAF 23/471 reads (5%) | catalogued as COSV60231351; called by muse, mutect2
- NPR3 | c.1215C>T p.S405= | Silent (SNP) | VAF 59/314 reads (19%) | catalogued as rs1191815267, COSV54090797, COSV99423827; called by muse, mutect2, varscan2
- NUTM2A | c.2484C>A p.S828= | Silent (SNP) | VAF 34/187 reads (18%) | called by mutect2, varscan2
- OR2T2 | c.906G>C p.L302= | Silent (SNP) | VAF 13/342 reads (4%) | catalogued as COSV100737714; called by muse, mutect2
- OR3A3 | c.606A>G p.Q202= | Silent (SNP) | VAF 71/336 reads (21%) | called by muse, mutect2, varscan2
- PLEC | c.3588G>T p.A1196= (on ENST00000322810 / NM_201380.4; = p.A1086= on NM_000445.5) | Silent (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- PRPS1 | c.250C>A p.R84= | Silent (SNP) | VAF 65/364 reads (18%) | called by muse, mutect2, varscan2
- RFC1 | c.1476A>G p.A492= | Silent (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- SKI | c.483C>G p.L161= | Silent (SNP) | VAF 20/420 reads (5%) | catalogued as rs1252325955; called by muse, mutect2
- SLC7A3 | c.1338G>A p.E446= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs905293206; called by muse, mutect2, varscan2
- SMIM10 | c.108C>T p.R36= | Silent (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- THSD7B | c.192G>T p.R64= | Silent (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- TMEM104 | c.663G>T p.P221= | Silent (SNP) | VAF 39/219 reads (18%) | catalogued as rs751527444; called by muse, mutect2, varscan2
- TNFAIP1 | c.870C>T p.D290= | Silent (SNP) | VAF 41/330 reads (12%) | called by muse, mutect2, varscan2
- TRARG1 | c.303C>A p.P101= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as rs768668936; called by muse, mutect2, varscan2
- TRIM29 | c.711G>A p.Q237= | Silent (SNP) | VAF 26/321 reads (8%) | catalogued as COSV59282544; called by muse, mutect2
- TRIM49B | c.150C>A p.V50= | Silent (SNP) | VAF 81/371 reads (22%) | called by muse, mutect2, varscan2
- TSPAN14 | c.340C>T p.L114= | Silent (SNP) | VAF 71/251 reads (28%) | called by muse, mutect2, varscan2
- TUBAL3 | c.993C>G p.V331= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- WDR19 | c.2211G>A p.Q737= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- AC090155.1 | n.194C>A | RNA (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850917 T>C | 3'Flank (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ATP8A2 | c.2211+1638A>T | Intron (SNP) | VAF 36/203 reads (18%) | called by muse, mutect2, varscan2
- C9orf62 | n.145G>C | RNA (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- CAMK2G | c.1191-20C>T | Intron (SNP) | VAF 17/79 reads (22%) | catalogued as rs751477682, COSV99989661; called by muse, mutect2
- CASP2 | c.967+57G>T | Intron (SNP) | VAF 89/443 reads (20%) | called by muse, mutect2, varscan2
- CDH23 | c.4845+40C>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- DCHS2 | n.575A>T | RNA (SNP) | VAF 45/269 reads (17%) | catalogued as rs767903439; called by muse, mutect2, varscan2
- HBG2 | c.*8G>A | 3'UTR (SNP) | VAF 36/296 reads (12%) | catalogued as rs780914729, COSV100400662; called by muse, mutect2, varscan2
- HMGA2 | c.249+43320C>A | Intron (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.613A>T | RNA (SNP) | VAF 22/324 reads (7%) | catalogued as rs760289558; called by muse, mutect2
- IGFN1 | c.1242-44C>T | Intron (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- LINC02337 | n.40-15686C>A | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MGAM | c.4618+1224C>A | Intron (SNP) | VAF 38/161 reads (24%) | catalogued as COSV72075045; called by muse, mutect2, varscan2
- MIR1302-7 | n.63A>G | RNA (SNP) | VAF 14/239 reads (6%) | called by muse, mutect2
- MIR510 | n.8C>A | RNA (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- MIR9-1HG | n.112C>T | RNA (SNP) | VAF 68/204 reads (33%) | catalogued as rs1356571141; called by muse, mutect2, varscan2
- PEX26 | c.*141G>T | 3'UTR (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948580 T>G | 3'Flank (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2
- RN7SL319P | chr15:75780807 G>T | 5'Flank (SNP) | VAF 64/442 reads (14%) | called by muse, mutect2, varscan2
- SLC35E3 | n.166C>G | RNA (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*20C>A | 3'UTR (SNP) | VAF 49/291 reads (17%) | called by muse, mutect2, varscan2
- TLE1 | c.1332-6824A>T | Intron (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- UBQLN2 | c.*47G>T | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- UGT2A3 | c.864+1971T>C | Intron (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- ZNF730 | c.-25G>T | 5'UTR (SNP) | VAF 28/120 reads (23%) | catalogued as rs779915538; called by muse, mutect2, varscan2
